Somatic mutation profile of tumor specimen TCGA-BT-A3PK-01A (aliquot TCGA-BT-A3PK-01A-21D-A21Z-08) from TCGA case TCGA-BT-A3PK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 80.3 years (29,314 days).
Specimen TCGA-BT-A3PK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21f814d6-02a2-42db-94fa-7b6faa4081ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A3PK-10A (Blood Derived Normal), aliquot TCGA-BT-A3PK-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d2301f1-78dc-4a1f-b4d6-12344c492fc7

The open-access MAF lists 376 somatic variants for this specimen: 280 protein-altering or splice-affecting, 88 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 248, Silent 88, Nonsense Mutation 16, Frame Shift Del 8, Splice Site 5, 3'UTR 2, RNA 2, 5'Flank 2, 5'UTR 1, Intron 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.3491G>A p.C1164Y | Missense Mutation (SNP) | VAF 34/173 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54335593, COSV54335605; called by muse, mutect2, varscan2
- ERCC2 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 9/110 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55540059, COSV55545034; called by muse, mutect2
- ABCA7 | c.5008G>C p.E1670Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV54038905; called by muse, mutect2
- ACCSL | c.1037A>C p.E346A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV66583200; called by muse, mutect2, varscan2
- ACO2 | c.1186T>A p.S396T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV53446245; called by muse, mutect2, varscan2
- ACRV1 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV59755602; called by muse, mutect2
- ACSBG1 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs768032072, COSV51904785; called by muse, mutect2, varscan2
- ADAMTS2 | c.2852C>A p.T951N | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV52398109; called by muse, mutect2, varscan2
- ADAMTS5 | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs371494692, COSV53177665; called by muse, mutect2, varscan2
- ADCY2 | c.2905C>T p.H969Y | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); catalogued as COSV57906355; called by muse, mutect2, varscan2
- ADD2 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV52459970; called by muse, mutect2, varscan2
- AFF3 | c.3528G>C p.E1176D | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.379); catalogued as COSV57879006; called by muse, mutect2
- AFF4 | c.2380C>G p.P794A | Missense Mutation (SNP) | VAF 83/591 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV54800963; called by muse, mutect2, varscan2
- AGBL1 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV69816951; called by muse, mutect2, varscan2
- AHI1 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs757196052, COSV55638040; called by muse, mutect2, varscan2
- AHNAK | c.10129G>C p.D3377H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770575968, COSV57235409; called by muse, mutect2
- AHNAK | c.9846G>C p.K3282N | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV57235427; called by muse, mutect2
- AHNAK | c.7711G>C p.E2571Q | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV57235475; called by muse, mutect2
- ALMS1 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV52525000; called by muse, mutect2, varscan2
- AMN | c.129C>A p.C43* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV54485898; called by muse, mutect2, varscan2
- ANGEL1 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs747200123, COSV51873786; called by muse, mutect2
- ANKRD17 | c.5302A>G p.T1768A | Missense Mutation (SNP) | VAF 165/314 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV58229423; called by muse, mutect2, varscan2
- ANLN | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV56080361, COSV99732962; called by muse, mutect2, varscan2
- ARID5B | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54432021; called by muse, mutect2, varscan2
- ARPC2 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV55286927; called by muse, mutect2, varscan2
- ATF7IP2 | c.408T>G p.D136E | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV61095808; called by muse, mutect2, varscan2
- ATM | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1064795257, COSV53782053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.7382G>C p.R2461P | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs768461085, COSV53782078, COSV99590879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBS7 | c.296A>T p.Q99L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV52660299; called by muse, mutect2, varscan2
- BCORL1 | c.3306G>T p.K1102N | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54409785; called by muse, mutect2, varscan2
- BTK | c.482A>C p.N161T | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs371085740, COSV58124489; called by muse, mutect2, varscan2
- C11orf80 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60931702; called by muse, mutect2, varscan2
- C12orf43 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1366518288, COSV56568853; called by muse, mutect2, varscan2
- C2orf16 | c.4223A>G p.D1408G | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as COSV62679109; called by muse, mutect2, varscan2
- CACNA1E | c.5832G>T p.Q1944H | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV62439347; called by muse, mutect2, varscan2
- CAMSAP2 | c.3520G>C p.D1174H (on ENST00000236925 / NM_001297707.2; = p.D1163H on NM_203459.3) | Missense Mutation (SNP) | VAF 6/177 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52679361; called by muse, mutect2
- CASZ1 | c.3749A>G p.Y1250C | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); catalogued as COSV59742152; called by muse, mutect2, varscan2
- CATSPERG | c.3400A>T p.M1134L | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV53054995; called by muse, mutect2, varscan2
- CCDC39 | c.1711A>C p.T571P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV56496115; called by muse, mutect2, varscan2
- CCDC8 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs760515077, COSV56775337; called by muse, mutect2
- CCN2 | c.1012T>C p.S338P | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.778); catalogued as COSV63467092; called by muse, mutect2, varscan2
- CCNL1 | c.1325A>T p.N442I | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as COSV55820864; called by muse, mutect2, varscan2
- CDK14 | c.689C>T p.P230L (on ENST00000380050 / NM_001287135.2; = p.P212L on NM_012395.3) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); catalogued as rs373874746; called by muse, mutect2, varscan2
- CEP104 | c.2433G>T p.K811N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV65520299; called by muse, mutect2
- CHD2 | c.1585C>A p.Q529K | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV67715361; called by muse, mutect2, varscan2
- CHD6 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58563547; called by muse, mutect2, varscan2
- CHD8 | c.3805G>C p.D1269H (on ENST00000646647 / NM_001170629.2; = p.D990H on NM_020920.4) | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67873131; called by muse, mutect2
- CHL1 | c.1260T>A p.D420E (on ENST00000397491 / NM_001253387.1; = p.D436E on NM_006614.4) | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV56610149; called by muse, mutect2
- CHRDL2 | c.295C>G p.H99D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV55225799; called by muse, mutect2, varscan2
- CLEC4G | c.866A>T p.K289I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61004301; called by muse, mutect2, varscan2
- CLMP | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV71650724; called by muse, mutect2
- CLPTM1L | c.581T>A p.V194E | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57993470; called by muse, mutect2, varscan2
- CNN2 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54049196; called by muse, mutect2
- CNNM4 | c.808A>T p.M270L | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as COSV65662366; called by muse, mutect2
- COL24A1 | c.3631C>G p.P1211A | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV65309012, COSV65316501; called by muse, mutect2, varscan2
- COL6A5 | c.6601G>C p.D2201H (on ENST00000312481; = p.D2197H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.125); catalogued as COSV55200246, COSV55218814; called by muse, mutect2
- COL7A1 | c.7831G>A p.G2611R | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56477446; called by muse, mutect2, varscan2
- COMP | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.746); catalogued as rs1351100052, COSV55876854; called by muse, mutect2, varscan2
- COX6A1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV57569438, COSV57569488, COSV57569746; called by muse, mutect2, varscan2
- CPA2 | c.1232T>C p.M411T | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55981774; called by muse, mutect2, varscan2
- CREB5 | c.1426C>A p.H476N (on ENST00000357727 / NM_182898.4; = p.H469N on NM_004904.3) | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63230220; called by muse, mutect2, varscan2
- CRYM | c.676G>C p.V226L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV54833664; called by muse, mutect2, varscan2
- CSKMT | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV63473746; called by muse, mutect2, varscan2
- CSNK1A1 | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV55799274; called by muse, mutect2
- CUL9 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52736389; called by muse, mutect2
- CYFIP1 | c.3738C>G p.I1246M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as COSV57417831; called by mutect2, varscan2
- DCAF11 | c.802G>C p.V268L | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV58111331; called by muse, mutect2
- DDN | c.1709A>G p.H570R | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV70405506; called by muse, mutect2
- DDX59 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as COSV58754893; called by muse, mutect2
- DGCR8 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV61229097; called by muse, mutect2, varscan2
- DGKG | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53965704, COSV99402300; called by muse, mutect2, varscan2
- DMXL2 | c.3078C>G p.F1026L | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51858748; called by muse, mutect2
- DNA2 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1003323248, COSV64430634; called by muse, mutect2, varscan2
- DNAH5 | c.1904A>G p.H635R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564653952, COSV54259171; ClinVar: uncertain significance; called by muse, mutect2
- DNM3 | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100798573, COSV62469868; called by muse, mutect2
- DOCK3 | c.2521G>T p.V841L | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV56513537; called by muse, mutect2, varscan2
- DOCK6 | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.377); catalogued as COSV53923988; called by muse, mutect2
- DSP | c.8582C>A p.S2861Y | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV60939123, COSV60941061; called by muse, mutect2
- DYNC2H1 | c.6579A>G p.I2193M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV62109849; called by muse, mutect2, varscan2
- DYNC2H1 | c.12199C>T p.R4067* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as rs376596919; called by muse, mutect2, varscan2
- DYNLT3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1347803731, COSV66079176; called by muse, mutect2, varscan2
- EDNRB | c.1058C>T p.T353I (on ENST00000377211 / NM_001201397.1; = p.T263I on NM_000115.5) | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV57524969, COSV57529053; called by muse, mutect2, varscan2
- ELMO1 | c.206T>A p.I69K | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV60330299; called by muse, mutect2
- EMID1 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV61831123; called by muse, mutect2, varscan2
- EPHB2 | c.1889-1G>C p.X630_splice (on ENST00000400191 / NM_001309193.2; = p.X631_splice on NM_004442.7) | Splice Site (SNP) | VAF 8/66 reads (12%) | catalogued as COSV65867567; called by muse, mutect2, varscan2
- ESRRA | c.457C>G p.R153G | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50006673, COSV50008569; called by muse, mutect2, varscan2
- FAM98C | c.734G>A p.W245* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as rs1272369318, COSV53038399; called by muse, mutect2
- FANCD2 | c.3786A>C p.E1262D | Missense Mutation (SNP) | VAF 78/455 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.501); catalogued as COSV55048348; called by muse, mutect2, varscan2
- FAT1 | c.6404T>A p.I2135N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71676393; called by muse, mutect2, varscan2
- FBF1 | c.1032C>A p.D344E (on ENST00000586717; = p.D358E on NM_001319193.1) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV59867647; called by mutect2, varscan2
- FBN1 | c.6715A>G p.R2239G | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV57333386; called by muse, mutect2, varscan2
- FBN1 | c.3937G>C p.G1313R | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as CM148677, COSV57316559; called by muse, mutect2
- FBXO42 | c.1570G>A p.G524R | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV65047085, COSV65047312; called by muse, mutect2
- FIG4 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57792217; called by muse, mutect2
- FMO5 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV54211534; called by muse, mutect2, varscan2
- FN1 | c.5092T>C p.Y1698H | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60566454; called by muse, mutect2, varscan2
- FREM2 | c.8017C>T p.R2673* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | catalogued as COSV54851227, COSV54852806; called by muse, mutect2, varscan2
- FUBP3 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60512641, COSV60513500; called by muse, mutect2
- GBP1 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV65084733; called by muse, mutect2, varscan2
- GC | c.832-1G>A p.X278_splice | Splice Site (SNP) | VAF 61/160 reads (38%) | catalogued as COSV56740652; called by muse, mutect2, varscan2
- GGA3 | c.436T>A p.S146T (on ENST00000537686 / NM_138619.4; = p.S113T on NM_014001.5) | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55459618; called by muse, mutect2, varscan2
- GPC2 | c.892+1G>T p.X298_splice | Splice Site (SNP) | VAF 75/903 reads (8%) | catalogued as COSV52786984; called by muse, mutect2
- GPR75 | c.1056C>G p.F352L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as COSV61831790, COSV61833438; called by muse, mutect2, varscan2
- GPRIN3 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs140505056, COSV60886814; called by mutect2, varscan2
- GRID1 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs770555419, COSV60049348; called by muse, mutect2, varscan2
- H4C9 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62890353; called by muse, mutect2, varscan2
- HNRNPA1 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52939318; called by muse, mutect2, varscan2
- HOMER1 | c.819A>C p.E273D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV56531540; called by muse, mutect2, varscan2
- HPS3 | c.1489G>A p.V497M | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV56058061; called by muse, mutect2
- HRNR | c.8389G>C p.G2797R | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as rs760612491, COSV64263772; called by muse, mutect2, varscan2
- HSF2 | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63774803; called by muse, mutect2
- INHBE | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 109/529 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56989397; called by muse, mutect2, varscan2
- INO80 | c.2147A>T p.D716V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62743541; called by muse, mutect2, varscan2
- IP6K3 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs371307963; called by muse, mutect2, varscan2
- IRAK3 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV54160655, COSV54166798; called by muse, mutect2, varscan2
- IRF5 | c.348G>C p.K116N | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50863223; called by muse, mutect2
- IRX6 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV51862722; called by muse, mutect2, varscan2
- ITPR2 | c.5222C>T p.S1741L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1257638846, COSV67277705; called by muse, mutect2, varscan2
- JAK3 | c.2978G>C p.W993S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71688120; called by muse, mutect2
- KCNH5 | c.2857C>G p.P953A | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV59782091; called by muse, mutect2
- KCNH5 | c.2542G>C p.D848H | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.28); catalogued as COSV59782098; called by muse, mutect2
- KCNK5 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63989561; called by muse, mutect2, varscan2
- KDM5B | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV52514576; called by muse, mutect2, varscan2
- KIAA1217 | c.3392A>G p.D1131G | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV56825523; called by muse, varscan2
- KIF21B | c.1950C>G p.I650M | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59768825; called by muse, mutect2
- KIF2A | c.1794A>C p.Q598H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV66947026; called by muse, mutect2, varscan2
- KLHL1 | c.705C>A p.D235E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.313); catalogued as COSV64787357; called by muse, mutect2, varscan2
- KLHL6 | c.913A>T p.I305F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV58070083; called by muse, mutect2
- KMT2B | c.2885G>A p.R962H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55862297; called by muse, mutect2, varscan2
- KMT2C | c.3325T>C p.W1109R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51516786; called by muse, mutect2, varscan2
- KMT2D | c.989C>G p.S330* | Nonsense Mutation (SNP) | VAF 10/285 reads (4%) | catalogued as COSV99983642; called by muse, mutect2
- KRIT1 | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.98); catalogued as COSV60667811; called by muse, mutect2, varscan2
- KRTAP13-2 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV67762394; called by muse, mutect2, varscan2
- L1CAM | c.3628G>A p.D1210N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs781964622, COSV62830716; called by muse, mutect2, varscan2
- LAMA1 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 33/229 reads (14%) | catalogued as COSV101057124, COSV67541525; called by muse, mutect2, varscan2
- LAMB4 | c.2648G>T p.G883V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as COSV52716506, COSV52733507; called by muse, mutect2, varscan2
- LARP1B | c.1397G>C p.R466P | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV52796603, COSV52804496; called by muse, mutect2, varscan2
- LHX8 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs761472990, COSV53954944; called by muse, mutect2, varscan2
- LMOD2 | c.1174T>C p.S392P | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV71755907; called by muse, mutect2, varscan2
- LRIG2 | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs772431120, COSV63164768; called by muse, mutect2, varscan2
- LRRTM4 | c.492G>C p.L164F | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs779230389, COSV69143220; called by muse, mutect2
- LTF | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV51612904; called by muse, mutect2, varscan2
- LTN1 | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63734462, COSV63735615; called by muse, mutect2, varscan2
- MAN1A1 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV63785236; called by muse, mutect2
- MAP3K4 | c.1018C>G p.H340D | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV62340146; called by muse, mutect2
- MAP3K4 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as COSV62340161; called by muse, mutect2, varscan2
- MFSD8 | c.286_304del p.L96Qfs*11 | Frame Shift Del (DEL) | VAF 17/138 reads (12%) | catalogued as COSV56553329; called by mutect2, pindel, varscan2
- MMUT | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51287262; called by muse, mutect2
- MYD88 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs768025686, COSV57181906; called by muse, mutect2, varscan2
- MYO16 | c.2730G>A p.R910= | Splice Region (SNP) | VAF 11/83 reads (13%) | catalogued as rs1352267750, COSV51823145; called by muse, mutect2, varscan2
- NCKAP5 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.898); catalogued as COSV58425427, COSV58434192; called by muse, mutect2, varscan2
- NEXN | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518512, COSV53945141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS1 | c.2407C>G p.H803D | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57624082; called by muse, mutect2
- NUP98 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.097); catalogued as COSV61440145; called by muse, mutect2, varscan2
- OGDHL | c.946A>T p.I316F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1398444838; called by muse, mutect2
- OR13G1 | c.872A>T p.N291I | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62945585; called by muse, mutect2
- OR1L1 | c.597C>A p.F199L (on ENST00000373686; = p.F149L on NM_001005236.3) | Missense Mutation (SNP) | VAF 60/493 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV58936999; called by muse, mutect2, varscan2
- OR2T1 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV63543101; called by muse, mutect2, varscan2
- OR51G2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as rs750568250, COSV58992987; called by muse, mutect2, varscan2
- OR52K2 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV57835333, COSV57835966; called by muse, mutect2, varscan2
- OR8H2 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 24/604 reads (4%) | catalogued as COSV57945621; called by muse, mutect2
- OR8H2 | c.818T>C p.V273A | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV57944443; called by muse, mutect2, varscan2
- OSBPL7 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50117623; called by muse, mutect2
- OTOGL | c.319A>G p.T107A (on ENST00000547103; = p.T98A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as COSV72007888; called by muse, mutect2, varscan2
- PADI1 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV64939423; called by muse, mutect2, varscan2
- PAPOLA | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53486401; called by muse, mutect2
- PARPBP | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.967); catalogued as COSV59674366, COSV59677421; called by muse, mutect2
- PCDHA10 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV56555256; called by muse, mutect2, varscan2
- PCDHB7 | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as COSV50831670; called by muse, mutect2, varscan2
- PCK1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs369101907, COSV60131704; called by muse, mutect2
- PCLO | c.10864G>A p.V3622I | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV61676972; called by muse, mutect2, varscan2
- PCLO | c.10633G>A p.A3545T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.068); catalogued as COSV61676984; called by muse, mutect2, varscan2
- PGBD1 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV52556735; called by muse, varscan2
- PKHD1 | c.9635T>C p.F3212S | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61898806; called by muse, mutect2, varscan2
- PKHD1 | c.5872A>T p.T1958S | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV61898819; called by muse, mutect2
- PKHD1 | c.5870A>G p.D1957G | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.121); catalogued as COSV61898829; called by muse, mutect2
- PLB1 | c.3048G>T p.W1016C | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1221477920, COSV59825838, COSV59838287; called by muse, mutect2, varscan2
- PLEKHA5 | c.1031T>A p.V344E | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54714932; called by muse, mutect2, varscan2
- PLEKHG1 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV62051996; called by muse, mutect2
- PLK3 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59499592, COSV59501554; called by muse, mutect2
- PMPCA | c.254G>C p.G85A | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53743861; called by muse, mutect2
- PNMA8B | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.079); catalogued as COSV66538005; called by muse, mutect2, varscan2
- POGK | c.990C>G p.H330Q | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1022465439, COSV63312633; called by muse, mutect2, varscan2
- PRKCA | c.316A>T p.I106F | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV52598598; called by muse, mutect2, varscan2
- PSMB6 | c.186T>A p.N62K | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54513511; called by muse, mutect2, varscan2
- PTCHD4 | c.1809C>G p.I603M | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59800226; called by muse, mutect2, varscan2
- RAB11A | c.431-1G>A p.X144_splice | Splice Site (SNP) | VAF 11/217 reads (5%) | catalogued as COSV56043182; called by muse, mutect2
- RAB36 | c.593T>A p.V198E | Missense Mutation (SNP) | VAF 38/387 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54076523; called by muse, mutect2
- RCBTB2 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60652309; called by muse, mutect2
- RLIM | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV60329587; called by muse, mutect2, varscan2
- RP1L1 | c.5575G>A p.D1859N | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66761460; called by muse, mutect2
- RPGRIP1L | c.3841G>C p.D1281H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV50921252, COSV99030260; called by muse, mutect2
- RSBN1L | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.146); catalogued as rs1035758053, COSV58511806; called by muse, varscan2
- RTL9 | c.3323C>G p.S1108C | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV71826647; called by muse, varscan2
- RUBCN | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs559652801, COSV56376233; called by muse, mutect2, varscan2
- RXYLT1 | c.556A>C p.N186H | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.912); catalogued as COSV54170461; called by muse, mutect2
- SALL1 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs745557411, COSV51761112; called by muse, mutect2, varscan2
- SCPEP1 | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 5/119 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs1301274731, COSV51856039; called by muse, mutect2
- SCRG1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56636291; called by muse, mutect2
- SDR16C5 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs767560400, COSV58128917; called by muse, mutect2, varscan2
- SEL1L | c.1918G>T p.G640W | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60923380; called by muse, mutect2, varscan2
- SEMA5B | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV52111000; called by muse, mutect2, varscan2
- SESN3 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV53588075; called by muse, mutect2, varscan2
- SFRP2 | c.118T>A p.C40S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56838771; called by muse, mutect2
- SGO1 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV55425598; called by muse, mutect2, varscan2
- SINHCAF | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61797088; called by muse, mutect2, varscan2
- SLC29A2 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60804381; called by muse, mutect2, varscan2
- SLC35B1 | c.247C>A p.Q83K (on ENST00000649906; = p.Q46K on NM_005827.4) | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53604622; called by muse, mutect2, varscan2
- SLC35B3 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59467683, COSV59470231; called by muse, mutect2, varscan2
- SLC39A10 | c.1697G>C p.G566A | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV62770145; called by muse, mutect2, varscan2
- SLC9C1 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.754); catalogued as COSV59894893; called by muse, mutect2
- SMC1B | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV62534077; called by muse, mutect2
- SMC4 | c.1888G>C p.D630H | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61008656; called by muse, mutect2, varscan2
- SNRNP48 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV60941069; called by muse, mutect2, varscan2
- SOAT1 | c.1558C>G p.Q520E | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV62657502; called by muse, mutect2
- SP1 | c.181T>G p.L61V (on ENST00000327443 / NM_138473.3; = p.L54V on NM_003109.1) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1202596377, COSV59405869; called by muse, mutect2, varscan2
- SPATA7 | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV50421332; called by muse, mutect2
- SRP68 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57165274; called by muse, mutect2
- STIL | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV54554693; called by muse, mutect2, varscan2
- SURF1 | c.437_445del p.A146_E148del | In Frame Del (DEL) | VAF 48/328 reads (15%) | catalogued as rs782387264; called by mutect2, varscan2
- SYNPO2L | c.2131C>G p.P711A (on ENST00000394810 / NM_001114133.3; = p.P487A on NM_024875.5) | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV65739396; called by muse, mutect2, varscan2
- TASOR | c.2677C>T p.P893S (on ENST00000355628 / NM_001365636.2; = p.P497S on NM_015224.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV62930288; called by muse, mutect2, varscan2
- TBR1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV67419498; called by muse, mutect2, varscan2
- TCHHL1 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV64288083; called by muse, mutect2
- TLN2 | c.3900G>C p.Q1300H | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV60897447; called by muse, mutect2, varscan2
- TM7SF3 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58002235; called by muse, mutect2, varscan2
- TMEM63A | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV64764372; called by muse, mutect2, varscan2
- TMPO | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54125782; called by muse, mutect2
- TMUB1 | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52542793; called by muse, mutect2, varscan2
- TNFAIP3 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV104378230, COSV52803386; called by muse, mutect2, varscan2
- TNFSF13B | c.81T>G p.C27W | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV65517594; called by muse, mutect2
- TNFSF13B | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1271524307, COSV65517602; called by muse, mutect2
- TOP3B | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs138357708; called by muse, mutect2
- TRHDE | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756258701, COSV53870948; called by muse, mutect2, varscan2
- TRIM58 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV63572764; called by muse, mutect2, varscan2
- TRMO | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs775142747, COSV64293715; called by muse, mutect2, varscan2
- TRPC4AP | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs143166417; called by muse, mutect2, varscan2
- TTC37 | c.2984T>A p.L995Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62457318; called by muse, mutect2, varscan2
- TTN | c.8185G>C p.E2729Q (on ENST00000591111; = p.E2683Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/165 reads (12%) | PolyPhen probably damaging (0.998); catalogued as COSV59991403, COSV60420123; called by muse, mutect2, varscan2
- TUBB6 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV52317104; called by muse, mutect2
- UFM1 | c.31A>T p.T11S | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV53496439; called by muse, mutect2, varscan2
- USP44 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV51568011; called by muse, mutect2, varscan2
- USP9X | c.5912A>G p.E1971G | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV61076841; called by muse, mutect2, varscan2
- VPS4B | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53071247; called by muse, mutect2, varscan2
- WDFY3 | c.5358T>A p.S1786R | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55717030; called by muse, mutect2, varscan2
- WDR26 | c.1633C>T p.H545Y (on ENST00000414423 / NM_001379403.1; = p.H445Y on NM_025160.7) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.358); catalogued as COSV54361390; called by muse, mutect2, varscan2
- XIRP1 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61137599; called by muse, mutect2
- YAP1 | c.1501C>T p.L501F (on ENST00000282441 / NM_001130145.3; = p.L447F on NM_006106.5) | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56779226, COSV56780463; called by muse, mutect2, varscan2
- ZBTB3 | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67360784, COSV67361584; called by mutect2, varscan2
- ZBTB38 | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV58544126; called by muse, mutect2, varscan2
- ZC3H14 | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs1435099944, COSV51774604; called by muse, mutect2
- ZKSCAN7 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 19/214 reads (9%) | catalogued as COSV56271822; called by muse, mutect2
- ZNF250 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52971257; called by muse, mutect2
- ZNF430 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55113345; called by muse, mutect2, varscan2
- ZNF638 | c.4535A>G p.E1512G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52499114; called by muse, varscan2
- AFF2 | c.464C>G p.S155* | Nonsense Mutation (SNP) | VAF 25/210 reads (12%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.2305del p.S769Afs*16 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- BCL6 | c.551_567del p.L184Hfs*22 | Frame Shift Del (DEL) | VAF 13/147 reads (9%) | called by mutect2, pindel
- BEX3 | c.335G>T p.*112Lext*11 | Nonstop Mutation (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- CHD6 | c.7859G>T p.G2620V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- COL4A3 | c.4323G>A p.W1441* | Nonsense Mutation (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- DGKZ | c.2568G>T p.K856N (on ENST00000454345 / NM_001105540.2; = p.K668N on NM_003646.4) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2
- DHRS9 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2
- HTRA2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2
- IGHV4-59 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); called by muse, mutect2
- MAPK1IP1L | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- MYOM1 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 11/218 reads (5%) | called by muse, mutect2
- NCF4 | c.235_239del p.S79Cfs*47 | Frame Shift Del (DEL) | VAF 19/135 reads (14%) | called by mutect2, pindel, varscan2
- NUTM1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2
- PTPN3 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- RABEP2 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 20/248 reads (8%) | called by muse, mutect2
- REEP3 | c.443T>G p.L148* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- SORL1 | c.2341_2356delinsAGA p.Q781Rfs*33 | Frame Shift Del (DEL) | VAF 36/233 reads (15%) | called by pindel, varscan2*
- SURF6 | c.298_302del p.P100Rfs*6 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | called by mutect2, varscan2
- TRIT1 | c.1117-4_1124delinsG p.X373_splice | Splice Site (DEL) | VAF 25/185 reads (14%) | called by pindel, varscan2*
- UBE2I | c.303_316del p.K101Nfs*17 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- ZBTB38 | c.2320A>G p.I774V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- ZNF35 | c.1006T>C p.C336R | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF770 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- ADAD1 | c.660A>G p.L220= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV56646062; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3225G>A p.L1075= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV54440614; called by muse, mutect2
- ALPI | c.102G>A p.Q34= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs768049873, COSV55016537, COSV99786196; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7059A>G p.P2353= | Silent (SNP) | VAF 41/216 reads (19%) | catalogued as COSV51861118; called by muse, mutect2, varscan2
- ANKRD34B | c.393A>G p.T131= | Silent (SNP) | VAF 26/179 reads (15%) | catalogued as COSV58614701; called by muse, mutect2, varscan2
- APAF1 | c.2121C>T p.F707= (on ENST00000551964 / NM_181861.2; = p.F696= on NM_001160.3) | Silent (SNP) | VAF 24/254 reads (9%) | catalogued as COSV59669576; called by muse, mutect2
- ATR | c.4995G>A p.K1665= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV63394090; called by muse, mutect2
- BPIFB6 | c.621G>C p.L207= | Silent (SNP) | VAF 33/460 reads (7%) | catalogued as COSV62757028; called by muse, mutect2
- C4BPA | c.714C>T p.T238= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV65536055, COSV65537948; called by muse, mutect2, varscan2
- CD2BP2 | c.114G>A p.G38= | Silent (SNP) | VAF 33/511 reads (6%) | catalogued as rs770046139, COSV59770129; called by muse, mutect2
- CELSR3 | c.6420C>A p.P2140= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV51182056; called by muse, mutect2
- CHD8 | c.3996G>A p.Q1332= (on ENST00000646647 / NM_001170629.2; = p.Q1053= on NM_020920.4) | Silent (SNP) | VAF 14/226 reads (6%) | catalogued as rs781129091, COSV63219711, COSV63219855; called by muse, mutect2
- CLYBL | c.69G>A p.A23= | Silent (SNP) | VAF 38/255 reads (15%) | catalogued as rs758550272, COSV59221123; called by muse, mutect2, varscan2
- CUX1 | c.3786G>T p.A1262= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs140169027, COSV52919615; called by muse, mutect2, varscan2
- CYP19A1 | c.571C>T p.L191= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as COSV53060588; called by muse, mutect2
- DNAH3 | c.9981T>C p.N3327= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as rs754435712, COSV54526529, COSV54559617; called by muse, mutect2
- DNAJC27 | c.258C>T p.Y86= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- DSC3 | c.2160G>C p.G720= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV64575999; called by muse, mutect2, varscan2
- DZIP3 | c.993T>G p.P331= | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as COSV64314351; called by muse, mutect2, varscan2
- EGFR | c.444G>A p.V148= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs895828689, COSV51858688; called by muse, mutect2, varscan2
- EGR2 | c.744C>G p.P248= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as COSV54346565, COSV54349296; called by muse, mutect2, varscan2
- EGR2 | c.42C>T p.L14= | Silent (SNP) | VAF 32/508 reads (6%) | catalogued as COSV54349309; called by muse, mutect2
- ERCC6L2 | c.1617G>A p.V539= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as COSV56634939; called by muse, mutect2, varscan2
- FMO4 | c.1392A>G p.G464= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as COSV63002082; called by muse, mutect2, varscan2
- FSTL4 | c.1572C>A p.V524= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as COSV54789581; called by muse, mutect2, varscan2
- FZD1 | c.621C>T p.F207= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV55313911; called by muse, mutect2, varscan2
- GABRB1 | c.1314C>G p.V438= | Silent (SNP) | VAF 21/196 reads (11%) | catalogued as rs764510481, COSV55003753; called by muse, mutect2, varscan2
- GNAZ | c.504T>C p.Y168= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV50742994; called by muse, mutect2, varscan2
- GSK3B | c.234A>G p.S78= | Silent (SNP) | VAF 49/311 reads (16%) | catalogued as rs763828967, COSV51784456; called by muse, mutect2, varscan2
- HADHA | c.2217C>T p.A739= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV101024027; called by muse, mutect2
- HAL | c.1821C>T p.L607= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV54120911; called by muse, mutect2, varscan2
- HERC6 | c.2133T>A p.P711= | Silent (SNP) | VAF 15/157 reads (10%) | catalogued as rs765879685, COSV52035865; called by muse, mutect2, varscan2
- HUS1 | c.471T>C p.S157= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV51840752; called by muse, mutect2, varscan2
- IL1B | c.378C>G p.L126= | Silent (SNP) | VAF 21/213 reads (10%) | catalogued as COSV54523596; called by muse, mutect2
- KDM5A | c.2355G>A p.R785= | Silent (SNP) | VAF 17/183 reads (9%) | catalogued as COSV66997028; called by muse, mutect2, varscan2
- KIAA1109 | c.1470C>T p.F490= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV52671755; called by muse, mutect2
- KNL1 | c.5247C>T p.I1749= (on ENST00000346991 / NM_170589.5; = p.I1723= on NM_144508.5) | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV61161849; called by muse, mutect2, varscan2
- LAMA5 | c.4182G>A p.L1394= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as COSV53375025; called by muse, mutect2, varscan2
- LMO7 | c.2829A>G p.A943= (on ENST00000357063; = p.A624= on NM_005358.5) | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV58552061; called by muse, mutect2, varscan2
- LRRIQ1 | c.2440C>T p.L814= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as rs773359954, COSV67840722; called by muse, mutect2, varscan2
- MACF1 | c.9498A>G p.Q3166= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs1432780825, COSV57150326; called by muse, mutect2, varscan2
- MAPK7 | c.883C>A p.R295= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV55192284; called by muse, mutect2, varscan2
- MAST4 | c.2808C>A p.T936= (on ENST00000403625 / NM_001164664.2; = p.T747= on NM_015183.3) | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- MDC1 | c.1032C>T p.V344= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as COSV64528588; called by muse, mutect2, varscan2
- METTL7A | c.30G>C p.L10= | Silent (SNP) | VAF 32/203 reads (16%) | catalogued as COSV59841559; called by muse, mutect2, varscan2
- MIB1 | c.177C>T p.N59= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV55096034; called by muse, mutect2, varscan2
- MRPL20 | c.414T>C p.P138= | Silent (SNP) | VAF 40/309 reads (13%) | catalogued as rs1365166912, COSV61224710; called by muse, mutect2, varscan2
- MTX2 | c.69A>G p.T23= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as COSV50890117; called by muse, mutect2, varscan2
- NCKAP5 | c.285C>A p.T95= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs754281481, COSV58464858; called by muse, mutect2, varscan2
- NEB | c.3192T>C p.Y1064= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV51468571; called by muse, mutect2
- NOL4 | c.1224G>A p.L408= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs1257647495, COSV52365510; called by muse, varscan2
- NTRK3 | c.807G>C p.T269= | Silent (SNP) | VAF 21/230 reads (9%) | catalogued as COSV100447029, COSV58126720; called by muse, mutect2
- PAQR7 | c.423G>A p.L141= | Silent (SNP) | VAF 43/264 reads (16%) | catalogued as COSV65352239; called by muse, mutect2, varscan2
- PHYKPL | c.1197G>C p.L399= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV57427377; called by muse, mutect2
- PRKCD | c.705T>C p.V235= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as COSV57852591; called by muse, mutect2, varscan2
- PTCHD3 | c.45G>A p.K15= | Silent (SNP) | VAF 41/254 reads (16%) | catalogued as COSV71257337; called by muse, mutect2, varscan2
- PTPN3 | c.2227T>C p.L743= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV52712355; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1233C>T p.I411= | Silent (SNP) | VAF 42/209 reads (20%) | catalogued as COSV52865335; called by muse, mutect2, varscan2
- RIPOR1 | c.2256G>T p.T752= (on ENST00000379312 / NM_001193522.2; = p.T748= on NM_024519.4) | Silent (SNP) | VAF 54/262 reads (21%) | catalogued as COSV50221911, COSV50291368; called by muse, mutect2, varscan2
- RMND5B | c.718C>T p.L240= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs979710560; called by muse, mutect2, varscan2
- SAXO2 | c.900T>C p.I300= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV59755724; called by muse, mutect2, varscan2
- SCAP | c.3037C>T p.L1013= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV55549497; called by muse, mutect2, varscan2
- SEMA3G | c.1392C>G p.L464= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV51599067; called by muse, mutect2, varscan2
- SHANK1 | c.687G>T p.V229= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV53265146; called by muse, mutect2
- SLC2A6 | c.1497C>T p.R499= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs367812993; called by muse, mutect2, varscan2
- SLC4A8 | c.1743T>C p.D581= | Silent (SNP) | VAF 35/200 reads (18%) | catalogued as COSV60659642; called by muse, mutect2, varscan2
- SLC66A2 | c.723C>T p.D241= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60271084; called by muse, mutect2, varscan2
- SLC9A3 | c.1389G>A p.L463= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV53806351; called by muse, mutect2, varscan2
- SMG5 | c.2247T>C p.F749= | Silent (SNP) | VAF 30/243 reads (12%) | catalogued as rs768436550, COSV62438419; called by muse, mutect2, varscan2
- SNX4 | c.1347G>A p.K449= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as rs779628446, COSV52540978; called by muse, mutect2, varscan2
- SPTBN5 | c.2979C>G p.A993= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- SRR | c.255A>C p.G85= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV56787624; called by muse, mutect2, varscan2
- STON2 | c.1839A>G p.S613= (on ENST00000649389 / NM_001366849.2; = p.S556= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV50858078; called by mutect2, varscan2
- SYNJ2 | c.3867A>G p.P1289= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV62901546; called by muse, mutect2, varscan2
- TCHHL1 | c.12C>G p.L4= | Silent (SNP) | VAF 9/135 reads (7%) | catalogued as COSV64288088; called by muse, mutect2
- TEAD1 | c.408T>A p.I136= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV57572650; called by muse, mutect2
- TECPR2 | c.2565A>G p.A855= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV63974982; called by muse, mutect2
- TMEM61 | c.564T>C p.S188= | Silent (SNP) | VAF 110/359 reads (31%) | catalogued as COSV64874024; called by muse, mutect2, varscan2
- TPM3 | c.798G>A p.L266= | Silent (SNP) | VAF 11/183 reads (6%) | catalogued as COSV55140120; called by muse, mutect2
- TRAV7 | c.205T>C p.L69= | Silent (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- TTLL1 | c.672G>A p.V224= | Silent (SNP) | VAF 9/228 reads (4%) | catalogued as COSV56741177; called by muse, mutect2
- VPS13A | c.7245C>G p.L2415= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as COSV62441405; called by muse, mutect2
- VPS13C | c.10368A>G p.A3456= (on ENST00000644861 / NM_020821.3; = p.A3413= on NM_017684.5) | Silent (SNP) | VAF 56/347 reads (16%) | catalogued as COSV51429626; called by muse, mutect2, varscan2
- VPS13D | c.8892C>T p.T2964= | Silent (SNP) | VAF 24/219 reads (11%) | catalogued as COSV50708244; called by muse, mutect2, varscan2
- WNT10A | c.165C>T p.L55= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV51464072; called by muse, mutect2, varscan2
- ZBTB40 | c.54C>T p.C18= | Silent (SNP) | VAF 17/175 reads (10%) | catalogued as COSV65146691; called by muse, mutect2
- ZNF2 | c.1146T>C p.Y382= (on ENST00000611147 / NM_001291605.2; = p.Y369= on NM_021088.4) | Silent (SNP) | VAF 42/266 reads (16%) | catalogued as COSV54638596; called by muse, mutect2, varscan2
- ZNF343 | c.1779C>T p.I593= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs1164434581, COSV53854235; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503799 G>T | 5'Flank (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505380 C>T | 5'Flank (SNP) | VAF 11/51 reads (22%) | catalogued as rs760239213; called by muse, mutect2, varscan2
- C12orf77 | n.383C>G | RNA (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- FGFR3 | c.*784C>T | 3'UTR (SNP) | VAF 49/254 reads (19%) | catalogued as rs996231302, COSV53424727; called by muse, mutect2, varscan2
- HMGCS2 | c.-1G>A | 5'UTR (SNP) | VAF 12/60 reads (20%) | catalogued as COSV101024846; called by muse, mutect2, varscan2
- MIR1205 | n.60C>G | RNA (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- POR | c.*134C>A | 3'UTR (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- PPP1R12B | c.2491-18730C>G | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
